Somatic mutation profile of tumor specimen MP2PRT-PAVDVM-TMP1-A (aliquot MP2PRT-PAVDVM-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVDVM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (855 days).
Specimen MP2PRT-PAVDVM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc70bfcf-1053-4bcd-9dbb-adf262d4f4bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDVM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDVM-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ffaca49-0bb3-43f4-9c44-1953cbc98fa5

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Translation Start Site 1, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDON | c.1543C>T p.L515F | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs781110937; called by muse, mutect2
- TTC7B | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 153/441 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1290652526, COSV60627039; called by muse, mutect2, varscan2
- CACNA1A | c.3783C>A p.S1261R | Missense Mutation (SNP) | VAF 34/561 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RET | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 292/768 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBL1XR1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SEZ6L2 | c.1488C>T p.A496= (on ENST00000308713 / NM_001114099.3; = p.A426= on NM_012410.4) | Silent (SNP) | VAF 32/578 reads (6%) | catalogued as rs375673174; called by muse, mutect2
- IGHV1-45 | chr14:106511116 ins TCT | 5'Flank (INS) | VAF 11/98 reads (11%) | called by pindel, varscan2
